TCGA case TCGA-EE-A3JH — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e7cfa51-8965-4c11-8fef-077fd258fbe4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 54 years; Vital status: Alive.

Diagnoses (6)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 61.7 years (22,524 days); Days to diagnosis: 2,672 days (7.3 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Trunk.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 54.4 years (19,852 days); Year of diagnosis: 2003; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
4. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 55.8 years (20,389 days); Days to diagnosis: 537 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 537 days (1.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
5. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Small intestine, NOS. Age at diagnosis: 61.7 years (22,524 days); Days to diagnosis: 2,672 days (7.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,672 days (7.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Intrathoracic lymph nodes. Age at diagnosis: 63.4 years (23,161 days); Days to diagnosis: 3,309 days (9.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 3,309 days (9.1 years).
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (6 entries)
- Day 537 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 537 days (1.5 years).
- Day 2,672 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Small intestine, NOS; Days to progression: 2,672 days (7.3 years).
- Days to follow up: 3,096 days (8.5 years); Disease response: Tumor Free.
- Day 3,309 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 3,309 days (9.1 years).
- Days to follow up: 3,333 days (9.1 years); Disease response: Tumor Free.
- Days to follow up: 4,086 days (11.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A3JH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A3JH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-EE-A3JH-06A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A3JH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 1.3; Primary melanoma mitotic rate: 2; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,086 days; disease-specific survival: no event (censored), 4,086 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 537 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A3JH-06A-11D-A219-01): tumor purity 0.21, ploidy 2.91, whole-genome doublings 1.
